CGCI case HTMCP-03-06-02414 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20995c26-5612-4473-9b57-6307f30220e2

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 479 days (1.3 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T2b; AJCC clinical N: N0; AJCC clinical M: M0; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 479 days (1.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 26 days; Days to treatment end: 122 days; Number of cycles: 5; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 218 days; Days to treatment end: 232 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 419 days (1.1 years); Treatment dose: 57; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 24000; Treatment outcome: Progressive Disease; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5700; Treatment outcome: Progressive Disease; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 359 days; Disease response: With Tumor.
- Days to follow up: 398 days (1.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Overlapping lesion of vulva; Days to recurrence: 398 days (1.1 years).
- Days to follow up: 479 days (1.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 48.4 kg; Height: 157.5 cm; BMI: 19.5; CD4 count: 599; Haart treatment indicator: Yes; HIV viral load: 34; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 250.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02414-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02414-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Weight kg at diagnosis: 48.4 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 09; Pregnancies count miscarriage: 00; Pregnancies count induced abortion: 00; Pregnancies count ectopic: 00; Pregnancies count stillbirth: 00; Total pregnancy count: 09; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2014; Nadir cd4 counts: 0250; HIV rna load at diagnosis: 000034; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0599.
- Follow-up form 1, Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, Treatment, Radiation therapy info: Radiation treatment reason not completed other: Passed away; Radiation therapy xrt type: External beam radiation.
- Follow-up form 2, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Introitus and clitoris; New tumor event surgery: No; New tumor event radiation treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 5; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Progression; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 3: Treatment type: Radiation Therapy; Radiation therapy end: No; Radiation therapy total dosage: 57; Treatment best response: Clinical Progressive Disease.
